Surgical pathology report (de-identified scan), TCGA case TCGA-22-A5C4, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-22-A5C4-01A (Primary Tumor).

[page 1 of 2]
Criteria	W 12/21/12	Yes	No
Prior Malignancy History	OMF-OR	✓	

SLIDE DISPOSITION:

DIAGNOSIS:

- A. Lymph nodes, right lower paratracheal (station 4R), biopsy:
Fragments of lymph nodes, negative for tumor.
- B. Lymph nodes, subcarinal (station 7), biopsy: Fragments of lymph nodes, negative for tumor.
- C. Lymph nodes, right pulmonary ligament (station 9R), biopsy:
Fragments of lymph nodes, negative for tumor.
- D. Lung, right, pneumonectomy: Invasive grade 4 (of 4) squamous cell carcinoma forming a well-circumscribed partially necrotic 6.3 x 5.2 x 3.4 cm central mass. Visceral pleural invasion is absent. The non-neoplastic lung parenchyma shows respiratory bronchiolitis. The bronchial margin is negative for tumor by 1.8 cm. No tumor is identified in multiple (17) intrapulmonary peribronchial nodes.

AJCC stage (with available surgical material): pT2bN0 (7th edition).

This final pathology report is based on the gross/macrosopic examination and frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

GROSS DESCRIPTION:

- A. Received fresh labeled "station 4 right lymph nodes" is a 5.4 x 1.9 x 0.8 cm aggregate of fragmented lymphatic tissue, which is entirely submitted. Grossed by
- B. Received fresh labeled "station 7 lymph nodes" is a 2.5 x 2.5 x 1.0 cm aggregate of fragmented lymphatic tissue, which is entirely submitted. Grossed by
- C. Received fresh labeled "station 9 right lymph nodes" is a 1.1 x 1.0 x 0.4 cm aggregate of fragmented lymphatic tissue, which is entirely submitted. Grossed by
- D. Received fresh labeled "right lung" is a 685 gram pneumonectomy. There is a 6.3 x 5.2 x 3.4 cm well-circumscribed solid partially necrotic mass located centrally, 1.8 cm from the shaved bronchial margin. The mass does not umbilicate the visceral pleura. Multiple intrapulmonary peribronchial lymph nodes are identified. Representative sections are submitted. Research tissue collected, Grossed by

BLOCK SUMMARY:

Part A: Station 4 right lymph nodes

- 1 Station 4 Rt LN (A1)
- 2 Station 4 Rt LN (A2)
- 3 Station 4 Rt LN (A3)
- 4 Station 4 Rt LN (A4)
- 5 Station 4 Rt LN (A5)

ICD-O-3

Carcinoma, squamous cell NOS
8070/3

Site: Path B Lung NOS C34.9

C&CF B Lung, lower lobe C34.3

W 11/13

[page 2 of 2]
Part B: Station 7 lymph nodes

- 1 Station 7 LN (B1)
- 2 Station 7 LN (B2)

Part C: Station 9 right lymph nodes

- 1 Station 9 RT LN (C1)

Part D: Right lung

- 1 Bronchial margin 1
- 2 Bronchial margin 2
- 3 Peribronchial LN 3 (D1)
- 4 Mass to pleura
- 5 Mass 1
- 6 Mass 2
- 7 Mass 3
- 8 Mass 4
- 9 Peribronchial LN 4(D2)
- 10 Peribronchial LN 5(D3)
- 11 Peribronchial LN 1(D4)
- 12 Peribronchial LN 4(D5)
- 13 Peribronchial LN 2(D6)
- 14 Normal lung

Source: NCI Genomic Data Commons file 02a06379-7953-4613-a1ed-233c20522561 (TCGA-22-A5C4.4B2F6A48-A414-45A6-A729-4BBA1EF29021.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).